Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H4, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H4-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

Stomach, distal gastrectomy:

- ADVANCED GASTRIC CARCINOMA, SINGLE, LOWER THIRD OF STOMACH,
ANTRUM ALONG GREATER CURVATURE, AGC BORRMANN TYPE 3,
TUBULAR ADENOCARCINOMA, POORLY DIFFERENTIATED, MIXED TYPE,
7.5 x 4.5 x 1.0 cm,

with

- 1) invasion to proper muscle
- 2) no involvement of distal and proximal resection margins
(distance to margin: distal, 0.5 cm;
proximal, 5.0 cm).
- 3) lymphovascular invasion: not identified.
- 4) perineural invasion: not identified.
- 5) METASTASIS IN 4 OF 21 LYMPH NODES (4/21)
(largest metastatic tumor size: 2 mm,
with extranodal extension: 0.3 mm).

ICD-O-3

adenocarcinoma, tubular 8211/3

Site: stomach, antrum C16.3

lw
9/27/12

<Addendum>

Final diagnosis: Stomach Intestinal Adenocarcinoma, Tubular Type per clarification by TSS.

Dx discrepancy form attached.

lw
10/9/12

Not mixed, per TSS spreadsheet

Diagnosis Discrepancy	☒ Mixed type	☐
Reviewed In (date):	Date Reviewed: 9/26/12	

lw
9/26/12

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: This form is to be completed when the pathologic diagnosis documented on the initial pathology report for this case is inconsistent with the diagnosis selected on the TCGA Case Quality Control Form.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnostic Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Mixed Stomach Tubular Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy Between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In the original pathology report (for the whole resected specimen), this tumor is described as a mixed type tumor. Review of TCGA sample top slide identified that this tumor is solely composed of an stomach adenocarcinoma, tubular type and the addendum was created as such.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 5ff4a497-0ff3-4162-81c3-5f8855bbdda8 (TCGA-HU-A4H4.77B699E5-0AAF-4EE1-88FC-3D1AAE277A41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).